Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UT-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma, mucinous endocervical
type 8482/3
Site: Cervix NOS C53.9
12/31/14

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1- "Biopsy of endocervical polypoid lesion":

Endocervical mucinous adenocarcinoma, invasive, poorly differentiated.
Perineural and angiolymphatic invasion not observed.

Immunohistochemistry exam

Morphologic features associated with the immunohistochemistry profile are compatible with endocervical mucinous adenocarcinoma poorly differentiated diagnosis.

Source: NCI Genomic Data Commons file 93ca7287-9e22-419f-b741-33f95d07cf71 (TCGA-VS-A9UT.2CBE50B6-D35F-495B-AF90-7536DBA459D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).